Gene-level copy-number profile of tumor specimen ALCH-B1XC-TTP1-A from ALCHEMIST case ALCH-B1XC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.8 years (22,563 days).
Specimen ALCH-B1XC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9ac73a9b-5f14-4fc8-8ae4-716a5332bffc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1XC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/ed45a10a-60a9-47ae-b035-71b5eebbf908

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 3,301; copy number 2: 53,167; copy number 3: 1,869; copy number 4: 2; copy number 5: 2; copy number 6: 1; copy number 27: 2.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–2,505,532, 3 genes: PLCH2, AL139246.1, AL139246.4.
- chr1:15,720,312–15,749,896, 4 genes (within-gene range 0–2): AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82.
- chr2:131,821,987–131,832,031, 2 genes: AC103564.3, AC103564.1.
- chr9:60,914,407–61,453,030, 12 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr12:131,639,396–131,664,704, 4 genes: LINC02414, AC117500.4, RNA5SP377, AC117500.1.
- chr14:103,519,667–103,562,831, 6 genes (within-gene range 0–2): CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5.
- chr16:15,125,242–15,155,002, 4 genes (within-gene range 0–2): PKD1P6, MIR6511B2, Y_RNA, MIR3180-4.
- chr16:89,159,146–89,164,245, 1 gene: LINC00304.
- chr16:89,171,748–89,201,651, 2 genes: CDH15, SLC22A31.
- chr17:68,125,777–68,159,043, 6 genes: LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3.
- chr17:75,588,058–75,626,849, 1 gene (within-gene range 0–2): MYO15B.
- chr17:75,633,434–75,641,404, 1 gene (within-gene range 0–2): SMIM5.
- chr19:531,760–542,092, 1 gene: CDC34.
- chr19:1,248,553–1,279,244, 4 genes: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr19:6,259,157–6,259,799, 1 gene (within-gene range 0–2): AC011471.2.
- chr20:63,343,223–63,378,401, 2 genes (within-gene range 0–2): CHRNA4, AL121827.1.
- chr22:41,909,554–41,914,667, 1 gene: SHISA8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,872,463–89,872,702, 1 gene, copy number 6: IGKV2D-38.
- chr16:848,525–849,065, 1 gene, copy number 5: AL031008.1.
- chr17:9,896,320–9,905,271, 1 gene, copy number 5: RCVRN.
- chr21:44,172,169–44,194,338, 2 genes, copy number 27: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 2,989. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
